Gene-level copy-number profile of tumor specimen TCGA-K4-A3WU-01B from TCGA case TCGA-K4-A3WU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 88.0 years (32,134 days).
Specimen TCGA-K4-A3WU-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.910a2022-7b7e-4c56-a1e6-043201642167.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A3WU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cef20f20-6da9-4d89-a527-62eb1cb353ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,380; copy number 2: 50,714; copy number 3: 6,394; copy number 4: 261; copy number 5: 58; copy number 6: 3; copy number 7: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A3WU-01B-11D-A23L-01): tumor purity 0.58, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:123,762,171–124,025,173, 4 genes, copy number 5: PSMD14P1, AC064859.1, RN7SKP102, AC079154.1.
- chr3:83,384,445–83,938,236, 3 genes, copy number 6: AC023503.1, AC092825.1, SRRM1P2.
- chr12:66,275,940–68,234,686, 29 genes, copy number 5–7: PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26.
- chr12:70,515,870–73,208,317, 34 genes, copy number 5 (within-gene range 4–5): PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
